Gene-level copy-number profile of tumor specimen C3L-02893-02 from CPTAC case C3L-02893, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 72.1 years (26,331 days).
Specimen C3L-02893-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ddc7154-0517-4f25-b0e3-e4bc0922b120.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02893-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/1dbe1529-ecf8-4f00-8530-d51c4ef54bdf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,094; copy number 2: 4,132; copy number 3: 6,498; copy number 4: 33,512; copy number 5: 4,233; copy number 6: 6,035; copy number 7: 2,646; copy number 8: 38; copy number 9: 47; copy number 10: 1; copy number 11: 58; copy number 12: 110.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 87 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:2,930,561–2,963,406, 3 genes, copy number 11: MFSD10, NOP14-AS1, NOP14.
- chr7:14,985,378–21,901,839, 84 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,094. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
